Somatic mutation profile of tumor specimen ER-AD7D-TTM1-A (aliquot ER-AD7D-TTM1-A-1-0-D-A49R-34) from EXCEPTIONAL_RESPONDERS case ER-AD7D, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 52.6 years (19,226 days).
Specimen ER-AD7D-TTM1-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ebbdbb2f-1071-4f99-8ef4-e4d49d69b3da.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ER-AD7D-NT1-A (Solid Tissue Normal), aliquot ER-AD7D-NT1-A-1-0-D-A578-34; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7e45595e-68cd-4d66-8010-55cfe96e6b74

The open-access MAF lists 133 somatic variants for this specimen: 95 protein-altering or splice-affecting, 25 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 78, Silent 25, Frame Shift Ins 7, Nonsense Mutation 5, 3'UTR 4, Frame Shift Del 4, Intron 4, 3'Flank 2, RNA 2, Splice Region 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1A | c.1787G>A p.R596H | Missense Mutation (SNP) | VAF 43/90 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.77); catalogued as rs1057523568, COSV61391392; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 137/327 reads (42%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- APC | c.4326del p.P1443Lfs*30 | Frame Shift Del (DEL) | VAF 31/132 reads (23%) | catalogued as COSV57332204; called by mutect2, pindel, varscan2
- ATP8B3 | c.3304C>T p.R1102C | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.353); catalogued as rs375897128; called by muse, mutect2, varscan2
- B4GALNT4 | c.2434C>T p.R812W | Missense Mutation (SNP) | VAF 43/81 reads (53%) | SIFT tolerated (0.25); PolyPhen benign (0.041); catalogued as rs759064827, COSV57322670; called by muse, mutect2, varscan2
- COL6A1 | c.2800G>A p.A934T | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as rs147716407; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DAO | c.857G>A p.R286H | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs566264618, COSV57323592; called by muse, mutect2, varscan2
- DOP1A | c.5591G>A p.R1864H | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); catalogued as rs367662678; called by muse, mutect2, varscan2
- EEF1A1 | c.754G>T p.D252Y | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV58548873, COSV58549955; called by muse, varscan2
- EPB41L4A | c.107C>T p.T36M | Missense Mutation (SNP) | VAF 53/104 reads (51%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as rs187394282, COSV99814183; called by muse, mutect2, varscan2
- ERGIC2 | c.455C>T p.T152I | Missense Mutation (SNP) | VAF 136/366 reads (37%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as rs371850211; called by muse, varscan2
- EVC2 | c.3530C>T p.A1177V | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.207); catalogued as rs544632500, COSV60394709; called by muse, mutect2, varscan2
- GRIP2 | c.619G>A p.D207N (on ENST00000619221; = p.D110N on NM_001080423.4) | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.927); catalogued as rs759832768, COSV56119540; called by muse, mutect2, varscan2
- HEATR1 | c.5459G>A p.R1820Q | Missense Mutation (SNP) | VAF 66/110 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100857660; called by muse, mutect2, varscan2
- IGSF10 | c.1057G>A p.V353M | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs761468860, COSV56783708; called by muse, mutect2, varscan2
- ITSN2 | c.1118G>A p.R373Q | Missense Mutation (SNP) | VAF 54/132 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.9); catalogued as rs1167369542, COSV100742781; called by muse, mutect2, varscan2
- LMO7 | c.1700C>T p.P567L (on ENST00000357063; = p.P297L on NM_015842.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/219 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs749281197; called by muse, mutect2, varscan2
- LRBA | c.3812G>A p.R1271Q | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as rs772811950; called by muse, mutect2, varscan2
- LRP2 | c.10028G>A p.R3343H | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated (0.28); PolyPhen benign (0.024); catalogued as rs765304399, COSV55565414; called by muse, mutect2, varscan2
- MAPK8IP3 | c.943C>T p.R315C | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); catalogued as rs760675508, COSV51717134; called by muse, mutect2, varscan2
- MKI67 | c.7454C>T p.P2485L | Missense Mutation (SNP) | VAF 48/93 reads (52%) | SIFT tolerated (0.1); PolyPhen benign (0.023); catalogued as rs998752390, COSV64077487; called by muse, mutect2, varscan2
- MYO15A | c.1867G>A p.G623S | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0); catalogued as rs1350627694; called by muse, mutect2, varscan2
- MYO15A | c.8261C>T p.T2754M | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.534); catalogued as rs766544188, COSV52761217; called by muse, mutect2, varscan2
- MYO9B | c.598G>A p.V200M | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762623209, COSV68276768; called by muse, mutect2, varscan2
- OR56A3 | c.679C>T p.R227* | Nonsense Mutation (SNP) | VAF 13/24 reads (54%) | catalogued as rs188845678, COSV61568609, COSV61569223; called by muse, mutect2, varscan2
- OR8K3 | c.667G>T p.V223L | Missense Mutation (SNP) | VAF 62/116 reads (53%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.021); catalogued as rs770790577; called by muse, mutect2, varscan2
- OSBPL5 | c.2401G>A p.G801S | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs758524305, COSV55144719; called by muse, mutect2, varscan2
- PAPPA | c.4088G>A p.R1363Q | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.61); PolyPhen benign (0.035); catalogued as rs765174536; called by muse, mutect2, varscan2
- PCDHGA11 | c.560C>T p.T187M | Missense Mutation (SNP) | VAF 38/67 reads (57%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.069); catalogued as rs753196648, COSV53936191; called by muse, mutect2, varscan2
- PCMTD2 | c.847C>T p.R283C | Missense Mutation (SNP) | VAF 74/196 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as rs756506348, COSV104382951; called by muse, mutect2, varscan2
- PTPN13 | c.3952C>T p.R1318C (on ENST00000411767 / NM_080683.3; = p.R1299C on NM_006264.3) | Missense Mutation (SNP) | VAF 88/197 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as rs756985714, COSV57408725; called by muse, mutect2, varscan2
- PTPRZ1 | c.5062C>A p.P1688T | Missense Mutation (SNP) | VAF 17/348 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as COSV101099928; called by muse, mutect2
- S100A14 | c.25G>A p.A9T | Missense Mutation (SNP) | VAF 34/138 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs770628756; called by muse, mutect2, varscan2
- SAMD1 | c.886C>T p.R296C | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.586); catalogued as rs770196527; called by muse, mutect2, varscan2
- SCN11A | c.617C>T p.A206V | Missense Mutation (SNP) | VAF 93/252 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs373405212; called by muse, mutect2, varscan2
- SERPINE1 | c.422G>A p.R141Q | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs145904727; called by muse, mutect2, varscan2
- SIL1 | c.218C>T p.T73M | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs371005800; called by muse, mutect2, varscan2
- SLC4A11 | c.845G>A p.R282H | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs751170291, CM107634; called by muse, mutect2, varscan2
- SNED1 | c.3287C>T p.A1096V | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.295); catalogued as rs1313090918, COSV60026471; called by muse, mutect2, varscan2
- TANC2 | c.3929C>T p.A1310V | Missense Mutation (SNP) | VAF 45/86 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1174223914; called by muse, mutect2, varscan2
- TGM6 | c.2029A>T p.S677C | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99171696; called by muse, mutect2, varscan2
- TMEM18 | c.242C>T p.S81L | Missense Mutation (SNP) | VAF 36/148 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as rs969982865, COSV55244620; called by muse, mutect2, varscan2
- TNFRSF19 | c.374C>T p.T125M | Missense Mutation (SNP) | VAF 38/72 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as rs373411330; called by muse, mutect2, varscan2
- TRIM46 | c.1580C>T p.P527L | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58112008, COSV58118368; called by muse, mutect2, varscan2
- TTN | c.15693G>T p.K5231N (on ENST00000591111; = p.K4304N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/67 reads (30%) | PolyPhen benign (0.399); catalogued as COSV100594594; called by muse, mutect2, varscan2
- TUBA3D | c.728G>T p.R243L | Missense Mutation (SNP) | VAF 33/63 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV58311623; called by muse, mutect2, varscan2
- VPS52 | c.1532G>A p.R511H | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761854873; called by muse, mutect2, varscan2
- ZNF354B | c.1285C>T p.R429* | Nonsense Mutation (SNP) | VAF 48/244 reads (20%) | catalogued as rs774680531; called by muse, mutect2, varscan2
- ZNF439 | c.838C>T p.H280Y | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.425); catalogued as COSV100397600, COSV58309521; called by muse, mutect2, varscan2
- ZSCAN1 | c.56C>T p.P19L | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as rs1349057042; called by muse, mutect2, varscan2
- AKIRIN2 | c.44C>A p.P15Q | Missense Mutation (SNP) | VAF 47/127 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANGPTL5 | c.519A>T p.E173D | Missense Mutation (SNP) | VAF 10/208 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.18); called by muse, mutect2
- APC | c.2379_2380del p.Y796Wfs*2 | Frame Shift Del (DEL) | VAF 30/78 reads (38%) | called by mutect2, pindel, varscan2
- ARFGEF1 | c.5414C>G p.P1805R | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.568); called by muse, mutect2, varscan2
- ARL14EP | c.178C>T p.H60Y | Missense Mutation (SNP) | VAF 49/201 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.607); called by muse, mutect2, varscan2
- ASB2 | c.1403C>T p.P468L | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- BCAS3 | c.172G>T p.E58* | Nonsense Mutation (SNP) | VAF 29/92 reads (32%) | called by muse, mutect2, varscan2
- CACNG8 | c.101T>G p.L34R | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CAND1 | c.2650A>T p.S884C | Missense Mutation (SNP) | VAF 11/128 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.001); called by muse, mutect2
- CBFB | c.54dup p.R19* | Frame Shift Ins (INS) | VAF 82/250 reads (33%) | called by mutect2, pindel, varscan2
- CBLL2 | c.898C>A p.P300T | Missense Mutation (SNP) | VAF 50/302 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.679); called by muse, mutect2, varscan2
- CCPG1 | c.442C>T p.Q148* | Nonsense Mutation (SNP) | VAF 25/46 reads (54%) | called by muse, mutect2, varscan2
- CEP83 | c.140C>T p.A47V | Missense Mutation (SNP) | VAF 25/150 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- CRH | c.518_521dup p.M174Ifs*37 | Frame Shift Ins (INS) | VAF 12/77 reads (16%) | called by mutect2, pindel, varscan2
- CTAGE9 | c.748G>A p.D250N | Missense Mutation (SNP) | VAF 47/310 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.085); called by muse, varscan2
- CYLC1 | c.722del p.N241Ifs*3 | Frame Shift Del (DEL) | VAF 280/585 reads (48%) | called by mutect2, pindel, varscan2
- DDX43 | c.39G>A p.W13* | Nonsense Mutation (SNP) | VAF 24/51 reads (47%) | called by muse, mutect2, varscan2
- DIDO1 | c.3470A>G p.K1157R | Missense Mutation (SNP) | VAF 12/125 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- EXOSC9 | c.695G>A p.C232Y | Missense Mutation (SNP) | VAF 44/212 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FEM1C | c.611_612dup p.C205Ifs*12 | Frame Shift Ins (INS) | VAF 31/161 reads (19%) | called by mutect2, pindel, varscan2
- FILIP1 | c.991C>T p.L331F | Missense Mutation (SNP) | VAF 39/77 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FRY | c.1286G>A p.R429Q | Missense Mutation (SNP) | VAF 200/354 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HLA-C | c.1031G>T p.S344I | Missense Mutation (SNP) | VAF 60/109 reads (55%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IFNA10 | c.535A>T p.T179S | Missense Mutation (SNP) | VAF 160/342 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- LRRC4C | c.1726A>T p.T576S | Missense Mutation (SNP) | VAF 35/66 reads (53%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MAP4K1 | c.1384C>T p.P462S | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- MPP1 | c.1097T>A p.V366E | Missense Mutation (SNP) | VAF 100/129 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MUC16 | c.36577C>T p.H12193Y | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- NUP160 | c.1686dup p.G563Rfs*21 | Frame Shift Ins (INS) | VAF 14/80 reads (18%) | called by mutect2, pindel, varscan2
- NUTM1 | c.3083T>G p.L1028R | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.997); called by muse, mutect2
- OR8B12 | c.238dup p.M80Nfs*31 | Frame Shift Ins (INS) | VAF 43/101 reads (43%) | called by mutect2, pindel, varscan2
- PGAM4 | c.614T>C p.I205T | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- PHC3 | c.2827G>A p.A943T (on ENST00000494943 / NM_001308116.2; = p.A955T on NM_024947.4) | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- PHF8 | c.2039G>A p.R680H (on ENST00000357988 / NM_001184896.1; = p.R644H on NM_015107.3) | Missense Mutation (SNP) | VAF 26/179 reads (15%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SMCO2 | c.818C>T p.P273L | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.774); called by muse, mutect2
- SORBS3 | c.96dup p.T33Dfs*15 | Frame Shift Ins (INS) | VAF 39/97 reads (40%) | called by mutect2, pindel, varscan2
- SORCS3 | c.3499del p.M1167* | Frame Shift Del (DEL) | VAF 9/41 reads (22%) | called by mutect2, pindel, varscan2
- TAF3 | c.1461dup p.N488Qfs*23 | Frame Shift Ins (INS) | VAF 95/244 reads (39%) | called by mutect2, pindel, varscan2
- TAS2R5 | c.122G>T p.W41L | Missense Mutation (SNP) | VAF 18/194 reads (9%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2
- TMED6 | c.162A>C p.E54D | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- TMEM106C | c.658A>T p.T220S | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- TNNT1 | c.-9C>T | Splice Region (SNP) | VAF 41/82 reads (50%) | called by muse, mutect2, varscan2
- VPS13B | c.5765A>C p.H1922P | Missense Mutation (SNP) | VAF 77/177 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZC3H7B | c.2869G>A p.G957R | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- ZSWIM1 | c.650T>C p.L217P | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- CACHD1 | c.717C>T p.V239= | Silent (SNP) | VAF 16/29 reads (55%) | called by muse, mutect2, varscan2
- CAVIN1 | c.747C>T p.R249= | Silent (SNP) | VAF 44/94 reads (47%) | called by muse, mutect2, varscan2
- COL4A4 | c.1425T>A p.G475= | Silent (SNP) | VAF 47/107 reads (44%) | called by muse, mutect2, varscan2
- DDX19A | c.792C>T p.P264= | Silent (SNP) | VAF 19/55 reads (35%) | called by muse, mutect2, varscan2
- DOCK10 | c.570G>A p.K190= | Silent (SNP) | VAF 86/166 reads (52%) | called by muse, mutect2, varscan2
- EBAG9 | c.606G>A p.K202= | Silent (SNP) | VAF 95/367 reads (26%) | catalogued as rs1242002404; called by muse, mutect2, varscan2
- GGTLC2 | c.333G>A p.P111= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as rs142640194; called by muse, mutect2, varscan2
- GSX1 | c.729C>T p.D243= | Silent (SNP) | VAF 19/75 reads (25%) | called by muse, mutect2, varscan2
- HOXA3 | c.102G>A p.P34= | Silent (SNP) | VAF 48/122 reads (39%) | catalogued as rs1408183066; called by muse, mutect2, varscan2
- INSM2 | c.1524C>T p.P508= | Silent (SNP) | VAF 26/41 reads (63%) | catalogued as COSV99355506; called by muse, mutect2, varscan2
- KIF14 | c.3388C>T p.L1130= | Silent (SNP) | VAF 122/506 reads (24%) | catalogued as rs768038028, COSV100950835; called by muse, mutect2, varscan2
- KRT6A | c.894G>A p.L298= | Silent (SNP) | VAF 39/91 reads (43%) | catalogued as COSV100416688; called by muse, mutect2, varscan2
- MRGPRX3 | c.123G>A p.A41= | Silent (SNP) | VAF 20/76 reads (26%) | catalogued as rs763180228, COSV66934112; called by muse, mutect2, varscan2
- MYT1L | c.2904G>A p.A968= | Silent (SNP) | VAF 30/85 reads (35%) | catalogued as rs745509665, COSV67703856; ClinVar: likely benign; called by muse, mutect2, varscan2
- NRG3 | c.1137A>G p.A379= | Silent (SNP) | VAF 30/135 reads (22%) | catalogued as COSV64578576; called by muse, mutect2, varscan2
- POLR3G | c.436C>T p.L146= (on ENST00000399107; = p.T136I on NM_006467.3 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 25/114 reads (22%) | called by muse, mutect2, varscan2
- SARDH | c.1614C>T p.Y538= | Silent (SNP) | VAF 5/40 reads (13%) | called by muse, mutect2, varscan2
- SYNE1 | c.24801C>T p.S8267= (on ENST00000367255 / NM_182961.4; = p.S8196= on NM_033071.3) | Silent (SNP) | VAF 23/64 reads (36%) | catalogued as rs754900484; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TMCO4 | c.576G>C p.L192= | Silent (SNP) | VAF 23/25 reads (92%) | called by muse, mutect2, varscan2
- TRHDE | c.48C>T p.S16= | Silent (SNP) | VAF 31/54 reads (57%) | called by muse, mutect2, varscan2
- TTN | c.46446A>T p.A15482= (on ENST00000591111; = p.A8058= on NM_003319.4) | Silent (SNP) | VAF 35/105 reads (33%) | catalogued as COSV60309183; called by muse, mutect2, varscan2
- TUBAL3 | c.603C>T p.T201= | Silent (SNP) | VAF 45/93 reads (48%) | called by muse, mutect2, varscan2
- WDR62 | c.3324C>T p.F1108= | Silent (SNP) | VAF 3/24 reads (13%) | called by muse, mutect2, varscan2
- ZBED4 | c.1755C>T p.T585= | Silent (SNP) | VAF 22/110 reads (20%) | called by muse, mutect2, varscan2
- ZFP92 | c.624C>T p.Y208= | Silent (SNP) | VAF 76/100 reads (76%) | catalogued as COSV58599121; called by muse, mutect2, varscan2
- ACKR3 | c.*632C>A | 3'UTR (SNP) | VAF 19/268 reads (7%) | called by muse, mutect2
- ADO | c.*2356T>G | 3'UTR (SNP) | VAF 11/129 reads (9%) | called by muse, mutect2
- AL627230.3 | c.76-118T>C | Intron (SNP) | VAF 35/380 reads (9%) | called by muse, mutect2
- BRWD1 | c.6571+88G>A | Intron (SNP) | VAF 116/417 reads (28%) | called by muse, mutect2, varscan2
- CHRM2 | chr7:137016836 T>G | 3'Flank (SNP) | VAF 62/282 reads (22%) | called by muse, mutect2
- CLDN5 | c.-10G>A | 5'UTR (SNP) | VAF 27/47 reads (57%) | called by muse, mutect2, varscan2
- CSNK1E | c.885+2114T>A | Intron (SNP) | VAF 9/33 reads (27%) | called by muse, mutect2, varscan2
- CTBP2 | c.58+12333C>T | Intron (SNP) | VAF 19/50 reads (38%) | catalogued as rs370105014; called by muse, mutect2, varscan2
- EP400P1 | n.714G>A | RNA (SNP) | VAF 16/112 reads (14%) | catalogued as rs769338917; called by muse, mutect2, varscan2
- GPR173 | c.*771G>A | 3'UTR (SNP) | VAF 16/99 reads (16%) | catalogued as rs1569225602; called by muse, mutect2, varscan2
- MUC19 | n.5021G>A | RNA (SNP) | VAF 390/999 reads (39%) | catalogued as rs918270003; called by muse, mutect2, varscan2
- SLCO2A1 | chr3:133928998 C>T | 3'Flank (SNP) | VAF 5/58 reads (9%) | called by muse, mutect2
- ZNF646 | c.*586C>T | 3'UTR (SNP) | VAF 27/76 reads (36%) | called by muse, mutect2, varscan2
